Somatic mutation profile of tumor specimen TCGA-C5-A1BE-01B (aliquot TCGA-C5-A1BE-01B-11D-A13W-08) from TCGA case TCGA-C5-A1BE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 65.0 years (23,727 days).
Specimen TCGA-C5-A1BE-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1873e144-b76f-48a9-9c67-37581798e670.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1BE-10A (Blood Derived Normal), aliquot TCGA-C5-A1BE-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fadb47d3-a1a5-4dde-b41a-1574f8ea9d25

The open-access MAF lists 78 somatic variants for this specimen: 57 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 82/99 reads (83%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACB | c.1918A>G p.N640D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV58139449; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2678C>T p.T893M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV65890166; called by muse, mutect2, varscan2
- AMY2A | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV70214676; called by muse, mutect2, varscan2
- ANK1 | c.1999-1G>T p.X667_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV55886739; called by muse, mutect2, varscan2
- APBA1 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs370688256; called by muse, mutect2, varscan2
- ATP1A4 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs762472595, COSV63624127; called by muse, mutect2, varscan2
- BCAS3 | c.2318C>T p.T773M (on ENST00000390652 / NM_001353144.2; = p.T758M on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs759264893, COSV66777260; called by muse, mutect2, varscan2
- BTK | c.1594C>G p.Q532E | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100437519; called by muse, mutect2
- CFAP43 | c.1256A>G p.D419G | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV53379382; called by muse, mutect2, varscan2
- CLIC5 | c.883+1G>A p.X295_splice (on ENST00000185206 / NM_001370649.1; = p.X136_splice on NM_016929.5) | Splice Site (SNP) | VAF 41/136 reads (30%) | catalogued as COSV51761525; called by muse, mutect2, varscan2
- COL22A1 | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs776592364, COSV57346570; called by muse, mutect2, varscan2
- CTNNBL1 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63745865; called by muse, mutect2, varscan2
- DEPDC1 | c.626_628del p.E209del | In Frame Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs776293996; called by pindel, varscan2
- DNAAF2 | c.1517C>A p.S506* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV53570740; called by muse, mutect2, varscan2
- DNAH3 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); catalogued as COSV54534230; called by muse, mutect2, varscan2
- DYNC1LI1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV56128318; called by muse, mutect2, varscan2
- EFTUD2 | c.2404C>T p.H802Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV53656012, COSV99493938; called by muse, mutect2, varscan2
- EIF2S1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV53605989; called by muse, mutect2, varscan2
- FOXO4 | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV58575724; called by muse, mutect2, varscan2
- HTATSF1 | c.492G>C p.Q164H | Missense Mutation (SNP) | VAF 160/360 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV54479896; called by muse, mutect2, varscan2
- INTS2 | c.3275C>T p.T1092I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV52002925; called by muse, varscan2
- JPH2 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV60697501; called by muse, mutect2, varscan2
- KIF16B | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735042, COSV61709400; called by muse, mutect2, varscan2
- KIF2C | c.1860A>T p.L620F | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV64765066; called by muse, mutect2, varscan2
- LRP1 | c.6166G>A p.G2056S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54517541; called by muse, mutect2, varscan2
- LRRC8B | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58376030; called by muse, mutect2, varscan2
- LRRC8B | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 81/280 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as COSV58376038; called by muse, mutect2, varscan2
- MAGEA1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs1216226226, COSV63118513; called by muse, mutect2, varscan2
- MAGT1 | c.92G>T p.R31I (on ENST00000618282 / NM_001367916.1; = p.R63I on NM_032121.5) | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV63782389; called by muse, mutect2, varscan2
- MAP3K13 | c.2313G>C p.Q771H | Missense Mutation (SNP) | VAF 83/709 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV53992199; called by muse, mutect2, varscan2
- MLNR | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54533295; called by muse, mutect2, varscan2
- MS4A13 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100981077; called by muse, mutect2
- NR2E1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1486393062, COSV64562378; called by muse, mutect2
- PABPC1 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs750623722, COSV100589479, COSV59407169; called by muse, mutect2
- PADI2 | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV64954176; called by muse, mutect2, varscan2
- PPP2R2D | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV70779276; called by muse, mutect2, varscan2
- PTPRF | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs969964085, COSV63446625; called by muse, mutect2, varscan2
- PTPRM | c.3862G>A p.D1288N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV59869567; called by muse, mutect2, varscan2
- RNF31 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as rs1335199536, COSV53759615, COSV53760434; called by muse, mutect2, varscan2
- SEMA4B | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764249282, COSV60174586; called by muse, mutect2, varscan2
- SETDB1 | c.3427G>T p.D1143Y | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV54987604; called by muse, mutect2, varscan2
- SGIP1 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV52773444; called by muse, mutect2, varscan2
- SNTA1 | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV54129809; called by muse, mutect2, varscan2
- SSX7 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV53340605; called by muse, mutect2, varscan2
- STK31 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as COSV63455924; called by muse, mutect2, varscan2
- TAS2R43 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67858624; called by muse, mutect2, varscan2
- USH2A | c.15419C>T p.S5140F | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV56397524; called by muse, mutect2, varscan2
- VWA3A | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV67013335; called by muse, mutect2, varscan2
- VWF | c.4049C>T p.A1350V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs764155969, COSV54624628; called by muse, mutect2, varscan2
- ZNF138 | c.894G>C p.Q298H (on ENST00000307355 / NM_001367572.1; = p.Q272H on NM_006524.4) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV56466257; called by muse, mutect2, varscan2
- ZNF185 | c.1802G>A p.S601N | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.461); catalogued as COSV100248317; called by muse, mutect2
- CYFIP1 | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- KIF21A | c.387del p.K129Nfs*3 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, varscan2
- OR1J1 | c.776_779dup p.F260Lfs*11 | Frame Shift Ins (INS) | VAF 52/224 reads (23%) | called by mutect2, pindel, varscan2
- OR4P4 | c.68del p.V23Afs*21 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | called by mutect2, pindel, varscan2
- UBE2NL | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- C1orf112 | c.1140C>T p.L380= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV53680607, COSV99610142; called by muse, mutect2, varscan2
- CDKN2AIP | c.576G>C p.R192= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs953732365, COSV56627575; called by muse, mutect2, varscan2
- DACT1 | c.1623G>A p.K541= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV60021950; called by muse, mutect2, varscan2
- ENOX2 | c.1452A>G p.K484= (on ENST00000338144 / NM_001382520.1; = p.K455= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV57654560; called by muse, mutect2, varscan2
- FGD2 | c.498C>T p.L166= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV51464748; called by muse, mutect2, varscan2
- GCG | c.276C>T p.H92= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as rs756760173, COSV64961777; called by muse, mutect2, varscan2
- GPT2 | c.708C>T p.D236= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as rs765286257, COSV60839361; called by muse, mutect2, varscan2
- GUCY2F | c.1785C>T p.F595= | Silent (SNP) | VAF 277/631 reads (44%) | catalogued as rs1299126087, COSV54298769; called by muse, mutect2, varscan2
- HCFC1 | c.4911G>A p.A1637= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs374047752, COSV100128780; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGB4 | c.2895C>T p.I965= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs373517123; called by muse, mutect2, varscan2
- KIAA1210 | c.3042G>C p.V1014= | Silent (SNP) | VAF 88/232 reads (38%) | catalogued as COSV68178355; called by mutect2, varscan2
- LIG4 | c.2442A>T p.R814= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV63597474; called by muse, mutect2, varscan2
- NEGR1 | c.214C>T p.L72= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs753378939, COSV60856733; called by muse, mutect2, varscan2
- NR3C2 | c.1368G>A p.S456= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs72645627, COSV60994948; called by muse, mutect2, varscan2
- PRDM14 | c.1569T>A p.G523= | Silent (SNP) | VAF 8/257 reads (3%) | catalogued as COSV99400038; called by muse, mutect2
- RSAD1 | c.603G>A p.P201= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs1012559867, COSV51956271; called by muse, mutect2, varscan2
- SLC17A1 | c.144G>A p.V48= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV55080257; called by muse, mutect2, varscan2
- TUBB1 | c.334C>T p.L112= | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as COSV53887357; called by muse, mutect2, varscan2
- XKR4 | c.1596C>T p.A532= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs751762924, COSV59326595; called by muse, mutect2, varscan2
- IPO5 | c.-134G>A | 5'UTR (SNP) | VAF 18/93 reads (19%) | catalogued as COSV55156366; called by muse, mutect2, varscan2
- ZNF14 | c.*1G>C | 3'UTR (SNP) | VAF 35/127 reads (28%) | catalogued as COSV100694030; called by muse, mutect2, varscan2
